Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3542, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3542-01A (Primary Tumor).

Diagnosis:

Resected section of colon (sigma) with an ulcerated colon carcinoma of histological type of a moderately differentiated colorectal adenocarcinoma, extending a maximum of 3 cm to a resection margin, and measuring 2.5 cm in diameter at the widest point. Invasive spreading of the tumor within all intestinal wall layers up to the bordering mesocolic adipose tissue, and with lymphangitic tumor branches in the margin area.

Tumor-free in the region of the oral and aboral resection margin.

Tumor stage therefore pT3 pN2 (4/18) L1 V0; G2, R0.

Source: NCI Genomic Data Commons file 3018713e-6b93-410f-bff9-be5eb51f2ff1 (TCGA-AA-3542.C13D322B-8984-440D-A279-4A3253A16F80.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).